Gene-level copy-number profile of tumor specimen TCGA-FI-A2F9-01A from TCGA case TCGA-FI-A2F9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 79.1 years (28,886 days).
Specimen TCGA-FI-A2F9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.20f6fe00-da13-4af4-a8e7-9c0cc1635fca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2F9-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 836 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df755d9b-4645-401a-a5a6-f6ca0ffe25c8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 8,921; copy number 3: 9,838; copy number 4: 31,857; copy number 5: 3,159; copy number 6: 4,181; copy number 7: 875; copy number 8: 238; copy number 9: 240; copy number 10: 83; copy number 11: 101; copy number 12: 44; copy number 13: 147; copy number 15: 41; copy number 16: 15; copy number 18: 36; copy number 21: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2F9-01A-11D-A17C-01): tumor purity 0.96, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 715 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,859,567–156,456,763, 36 genes, copy number 18 (within-gene range 5–18): SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1.
- chr3:49,198,428–49,786,542, 28 genes, copy number 10 (within-gene range 7–10): IHO1, AC121247.2, AC121247.1, C3orf62, Y_RNA, MIR4271, USP4, GPX1, RHOA, RHOA-IT1, TCTA, AC104452.1, AMT, NICN1, RNA5SP130, DAG1, BSN-DT, BSN, BSN-AS1, APEH, MST1, AC099668.1, RNF123, AMIGO3, GMPPB, IP6K1, COX6CP14, AC139451.1.
- chr3:52,903,572–53,813,733, 15 genes, copy number 12 (within-gene range 6–12): SFMBT1, AC096887.1, AC096887.2, SERBP1P3, RFT1, PRKCD, AC097015.1, TKT, DCP1A, Y_RNA, CACNA1D, SNORD38C, AC112218.1, AC092035.1, SNORD63.
- chr3:133,932,701–134,250,859, 4 genes, copy number 10–13 (within-gene range 4–13): SLCO2A1, LINC02000, RYK, HMGB3P14.
- chr4:1,356,581–1,359,461, 2 genes, copy number 9: AC078852.2, AC078852.1.
- chr4:1,550,284–1,856,156, 10 genes, copy number 13: AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1.
- chr5:56,451,627–56,606,232, 5 genes, copy number 9 (within-gene range 6–9): LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1.
- chr5:124,059,794–124,809,233, 11 genes, copy number 9: LINC01170, HMGB1P29, AC016556.1, AC025465.2, AC025465.4, AC025465.3, AC025465.1, ZNF608, AC112196.1, AC113398.2, AC113398.1.
- chr5:124,829,472–124,869,914, 2 genes, copy number 9: AC109464.1, AC109464.2.
- chr5:177,260,340–177,312,757, 6 genes, copy number 9: AC146507.3, AC146507.2, PRMT1P1, RAB24, MXD3, PRELID1.
- chr6:10,980,759–11,807,046, 19 genes, copy number 10–15 (within-gene range 6–15): ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3.
- chr6:31,441,667–31,897,687, 68 genes, copy number 11 (broad region; genes not listed).
- chr8:100,475,667–100,663,415, 6 genes, copy number 9 (within-gene range 5–9): AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1.
- chr9:3,526,723–3,691,814, 3 genes, copy number 9: RFX3-AS1, AL354977.2, AL354977.1.
- chr9:3,875,584–3,901,248, 2 genes, copy number 9: AL137071.1, GLIS3-AS1.
- chr9:136,196,250–137,273,542, 100 genes, copy number 13 (broad region; genes not listed).
- chr10:103,594,027–103,855,543, 1 gene, copy number 9 (within-gene range 6–9): SH3PXD2A.
- chr10:103,745,966–104,480,274, 20 genes, copy number 9: SH3PXD2A-AS1, AL133355.1, STN1, SLK, RN7SL524P, COL17A1, MIR936, SFR1, CFAP43, MIR609, GSTO1, MIR4482, GSTO2, ITPRIP, AL162742.1, AL162742.2, ITPRIP-AS1, CFAP58-DT, CFAP58, LINC02620.
- chr11:67,006,778–67,491,103, 29 genes, copy number 12 (within-gene range 4–12): SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP.
- chr12:55,973,913–56,103,505, 8 genes, copy number 21 (within-gene range 4–21): RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3.
- chr12:56,822,985–57,296,484, 25 genes, copy number 9 (within-gene range 4–9): AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16, AC026120.1, AC026120.3, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1.
- chr13:74,231,457–74,565,445, 8 genes, copy number 10: LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr13:98,142,562–98,577,940, 9 genes, copy number 11 (within-gene range 7–11): FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1.
- chr13:100,708,325–101,059,286, 3 genes, copy number 11 (within-gene range 6–11): NALCN-AS1, ARF4P3, LINC00411.
- chr13:110,148,963–110,813,084, 13 genes, copy number 11 (within-gene range 6–11): COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567.
- chr15:90,102,649–90,229,679, 4 genes, copy number 9 (within-gene range 2–9): IDH2-DT, SEMA4B, RN7SL346P, RPS12P26.
- chr16:2,771,414–3,256,633, 50 genes, copy number 9: ELOB, AC092117.1, PRSS33, SNORA3C, PRSS41, PRSS21, EIF1P4, ZG16B, PRSS30P, PRSS22, AC003965.2, AC003965.1, FLYWCH2, FLYWCH1, RPL23AP86, AC004034.1, KREMEN2, PKMYT1, PAQR4, AC004233.3, LINC00514, AC004233.1, AC004233.4, AC004233.2, CLDN9, CLDN6, TNFRSF12A, HCFC1R1, THOC6, BICDL2, AC108134.1, MMP25-AS1, MMP25, IL32, RNU1-125P, AC108134.3, RNU1-22P, ZSCAN10, ZNF213-AS1, AC108134.4, ZNF205, ZNF213, CASP16P, AC108134.2, AJ003147.1, AJ003147.2, OR1F1, OR1F2P, ZNF200, MEFV.
- chr17:1,344,275–1,900,082, 24 genes, copy number 9: YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1.
- chr17:39,461,486–39,864,312, 15 genes, copy number 16 (within-gene range 5–16): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:63,009,556–63,427,699, 1 gene, copy number 9 (within-gene range 4–9): TANC2.
- chr17:63,182,166–63,696,305, 21 genes, copy number 9 (within-gene range 4–9): DNAJB6P8, AC015923.1, AC005828.2, AC005828.7, AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6, DCAF7, RNU6-288P, TACO1, AC046185.2, MAP3K3, EEF1DP7.
- chr17:66,302,613–66,810,743, 1 gene, copy number 9 (within-gene range 4–9): PRKCA.
- chr17:66,638,271–67,245,989, 13 genes, copy number 9: RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48.
- chr17:74,950,742–75,785,893, 50 genes, copy number 9–13 (within-gene range 4–13): HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738.
- chr18:3,066,807–3,478,978, 15 genes, copy number 10: MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,897,069, 9 genes, copy number 10: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P.
- chr18:48,919,853–49,048,474, 4 genes, copy number 11: SMAD7, AC114684.1, AC016866.3, AC016866.1.
- chr18:49,049,687–49,126,479, 2 genes, copy number 11: MIR4744, AC016866.2.
- chr18:62,650,308–63,604,639, 15 genes, copy number 9 (within-gene range 5–9): RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13.
- chr20:63,528,001–64,313,132, 54 genes, copy number 10–15: PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
